Somatic mutation profile of tumor specimen 0DWNTM from CCDI case PBCNSK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.6 years (2,414 days).
Specimen 0DWNTM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41552a3a-5d87-4bd0-bbef-58a9874ab79c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DWNR0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/abfbceee-0530-444d-8a5a-a42632fae90a

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Nonsense Mutation 1, Silent 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DTHD1 | c.2075A>T p.E692V (on ENST00000456874; = p.E527V on NM_001136536.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/727 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- RIMKLB | c.350G>A p.W117* | Nonsense Mutation (SNP) | VAF 27/990 reads (3%) | called by muse, mutect2
- WDR91 | c.816C>A p.S272R | Missense Mutation (SNP) | VAF 81/504 reads (16%) | SIFT tolerated (0.48); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- XIRP2 | c.6349C>T p.P2117S (on ENST00000628543; = p.P2292S on NM_152381.6) | Missense Mutation (SNP) | VAF 40/768 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- CERS3 | c.861G>A p.T287= | Silent (SNP) | VAF 161/403 reads (40%) | catalogued as rs140012314, COSV99431660; called by muse, mutect2, varscan2
- EWSR1 | c.1581-19G>C | Intron (SNP) | VAF 12/268 reads (4%) | called by muse, mutect2
